Somatic mutation profile of tumor specimen C3L-01732-01 (aliquot CPT0099910009) from CPTAC case C3L-01732, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 84.1 years (30,733 days).
Specimen C3L-01732-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b950df1-fc14-4e99-8680-34a065542c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01732-31 (Blood Derived Normal), aliquot CPT0099960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92fd8c1c-7e24-404b-9c0b-51b080145f2e

The open-access MAF lists 880 somatic variants for this specimen: 583 protein-altering or splice-affecting, 154 silent, 143 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 364, Silent 154, Frame Shift Del 123, Intron 71, Frame Shift Ins 31, 3'UTR 28, Nonsense Mutation 23, Splice Region 19, RNA 17, 5'UTR 14, Splice Site 12, 3'Flank 7.

Variants (750 of 880; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 168/390 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374726386, CM067633; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 68/215 reads (32%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATM | c.2921+1G>A p.X974_splice | Splice Site (SNP) | VAF 136/377 reads (36%) | catalogued as rs587781558, CS991304, COSV53740769, COSV53748775, COSV53767471; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 192/459 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 8/150 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2
- ERBB3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 102/312 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778104039, COSV57252908; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 125/321 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 127/304 reads (42%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 67/183 reads (37%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.1599G>C p.Q533H | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1263928487; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 37/111 reads (33%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCB9 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs745962274; called by muse, mutect2, varscan2
- ABCF3 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs150420700; called by muse, mutect2, varscan2
- ABI3BP | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1005975720, COSV52551207; called by muse, mutect2, varscan2
- ABLIM2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs545161493, COSV99590972; called by muse, mutect2, varscan2
- ABTB2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.239); catalogued as rs373433790; called by muse, mutect2, varscan2
- ACOD1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV66291603; called by muse, mutect2, varscan2
- ADAD1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs200229076, COSV56642519, COSV56644466; called by muse, mutect2, varscan2
- ADCY6 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs748840221, COSV57167722; called by muse, mutect2, varscan2
- ADGRB2 | c.4117G>A p.A1373T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1325094137; called by muse, mutect2, varscan2
- ADGRV1 | c.3908dup p.L1303Ffs*39 | Frame Shift Ins (INS) | VAF 38/364 reads (10%) | catalogued as rs749681584; called by mutect2, pindel
- AGBL1 | c.3060T>C p.G1020= | Splice Region (SNP) | VAF 29/77 reads (38%) | catalogued as rs1209341562; called by muse, mutect2, varscan2
- AJUBA | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV52987032; called by muse, mutect2, varscan2
- AL136295.3 | c.523del p.G175Afs*15 | Frame Shift Del (DEL) | VAF 46/120 reads (38%) | catalogued as rs760463204; called by mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 83/232 reads (36%) | catalogued as rs756508755; called by mutect2, varscan2
- AMER2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs772426793, COSV63437389; called by muse, mutect2, varscan2
- ANTKMT | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1300492922, COSV53496739; called by muse, mutect2, varscan2
- AP000812.4 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs876657502; ClinVar: likely benign; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 71/235 reads (30%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- AR | c.1399G>A p.G467S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.012); catalogued as rs1346818973, COSV65952612; called by muse, mutect2, varscan2
- ARHGEF10 | c.3514G>A p.G1172R (on ENST00000398564; = p.G1147R on NM_014629.4) | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1212009927; called by muse, mutect2, varscan2
- ARHGEF26 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62843650; called by muse, mutect2, varscan2
- ATP2C1 | c.75del p.A26Qfs*21 | Frame Shift Del (DEL) | VAF 126/321 reads (39%) | catalogued as rs1559936852, COSV60757077; called by mutect2, varscan2
- BPIFB2 | c.588del p.V197Wfs*89 | Frame Shift Del (DEL) | VAF 69/170 reads (41%) | catalogued as COSV50063189; called by mutect2, pindel, varscan2
- BPIFB4 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs372134125; called by muse, mutect2, varscan2
- BRINP3 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.3); catalogued as rs200159768, COSV66530148; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | catalogued as rs746043904; called by mutect2, varscan2
- C1orf94 | c.1784G>A p.G595D (on ENST00000488417 / NM_001134734.2; = p.G405D on NM_032884.5) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs754716272, COSV64914862; called by muse, mutect2, varscan2
- C2orf69 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs755755680, COSV60666564; called by muse, mutect2, varscan2
- CACNA1E | c.4457C>T p.A1486V | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as rs759534975; called by muse, mutect2, varscan2
- CACNA1I | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs1338767684, COSV60811430; called by muse, mutect2
- CASKIN1 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs1208477025; called by muse, mutect2, varscan2
- CBLN4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50352509, COSV50353669; called by muse, mutect2, varscan2
- CCDC181 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs377162197; called by muse, mutect2, varscan2
- CDC42BPG | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs764957354; called by muse, mutect2, varscan2
- CDHR1 | c.1783-6G>A | Splice Region (SNP) | VAF 133/409 reads (33%) | catalogued as rs750881799; called by muse, mutect2, varscan2
- CEP170B | c.2206C>T p.R736C (on ENST00000453495; = p.R665C on NM_015005.3) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs971312565; called by muse, mutect2, varscan2
- CERK | c.1428del p.K477Rfs*74 | Frame Shift Del (DEL) | VAF 149/445 reads (33%) | catalogued as rs761362852; called by mutect2, pindel, varscan2
- CFH | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111064, CM156567; called by muse, mutect2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CGB8 | c.438del p.S147Afs*? | Frame Shift Del (DEL) | VAF 33/292 reads (11%) | catalogued as COSV56822738; called by mutect2, pindel, varscan2
- CGB8 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs746017552; called by mutect2, varscan2
- CHM | c.680T>G p.F227C | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753548; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 60/168 reads (36%) | catalogued as rs755424899; called by mutect2, varscan2
- CNTNAP5 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.997); catalogued as COSV101443122; called by muse, mutect2, varscan2
- CNTNAP5 | c.3613T>C p.S1205P | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs946930048, COSV70494135; called by muse, mutect2, varscan2
- COL11A1 | c.1735del p.R579Gfs*54 | Frame Shift Del (DEL) | VAF 99/294 reads (34%) | catalogued as COSV62195334; called by mutect2, pindel, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 47/166 reads (28%) | catalogued as rs760493024; called by mutect2, varscan2
- COL25A1 | c.1488del p.G497Efs*14 | Frame Shift Del (DEL) | VAF 71/231 reads (31%) | catalogued as COSV101211681; called by mutect2, pindel, varscan2
- COLGALT2 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780114815; called by muse, mutect2, varscan2
- CRB1 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs752917560; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 82/244 reads (34%) | catalogued as rs747437399; called by mutect2, varscan2
- CSNK1G1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 75/196 reads (38%) | catalogued as COSV57307102, COSV57312016; called by muse, mutect2, varscan2
- CTCF | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.414); catalogued as rs767996920, COSV50511527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCL9 | c.323dup p.K109Efs*47 | Frame Shift Ins (INS) | VAF 62/218 reads (28%) | catalogued as rs770761582; called by mutect2, varscan2
- CYFIP2 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.863); catalogued as rs746795054, COSV100558016; called by muse, mutect2, varscan2
- DCP1B | c.548del p.K183Rfs*2 | Frame Shift Del (DEL) | VAF 67/195 reads (34%) | catalogued as rs1191848585; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 56/118 reads (47%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX50 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 36/106 reads (34%) | catalogued as COSV65293267; called by muse, varscan2
- DIPK2B | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65005080; called by muse, mutect2, varscan2
- DISP3 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs576336989, COSV53829175, COSV99037595; called by muse, mutect2, varscan2
- DMD | c.9829G>A p.E3277K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as CM100271, COSV58936218; called by muse, varscan2
- DNAAF3 | c.1133G>A p.G378D (on ENST00000524407 / NM_001256715.2; = p.G425D on NM_178837.4) | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV61277872; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAJC2 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 67/188 reads (36%) | catalogued as rs1228594083, COSV50786843; called by muse, mutect2, varscan2
- DOCK6 | c.4577G>A p.R1526Q | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV53924044; called by muse, mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 132/412 reads (32%) | catalogued as rs750520568; called by mutect2, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 69/243 reads (28%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DSCAML1 | c.3121A>G p.T1041A (on ENST00000321322; = p.T981A on NM_020693.4) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1489840562; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 66/208 reads (32%) | catalogued as rs746509911; called by mutect2, varscan2
- ECEL1 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 157/434 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as rs1311950101; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | catalogued as rs748937918; called by mutect2, varscan2
- EPG5 | c.3014C>T p.T1005M | Missense Mutation (SNP) | VAF 24/417 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs890699630; ClinVar: uncertain significance; called by muse, mutect2
- EPHA1 | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs368297501; called by muse, mutect2, varscan2
- EPHA10 | c.2910C>A p.A970= | Splice Region (SNP) | VAF 124/285 reads (44%) | catalogued as rs767112577, COSV100361072; called by muse, mutect2, varscan2
- EPHA2 | c.843del p.F281Lfs*112 | Frame Shift Del (DEL) | VAF 32/380 reads (8%) | catalogued as COSV64454468; called by mutect2, pindel
- ERCC6 | c.1717_1720del p.C573Qfs*4 | Frame Shift Del (DEL) | VAF 147/405 reads (36%) | catalogued as rs766629930; called by pindel, varscan2
- ERLEC1 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99483087; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 128/294 reads (44%) | catalogued as rs779855268; called by mutect2, varscan2
- FAM114A1 | c.998dup p.N333Kfs*2 | Frame Shift Ins (INS) | VAF 52/184 reads (28%) | catalogued as rs1445635647; called by pindel, varscan2
- FAM200B | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1178148940, COSV101435846; called by muse, varscan2
- FAM205A | c.3811G>A p.G1271R | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1428968408; called by muse, mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 80/254 reads (31%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM47C | c.3052G>T p.A1018S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs373819113; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 72/160 reads (45%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT2 | c.10376G>C p.G3459A | Missense Mutation (SNP) | VAF 126/412 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745811126, COSV55816485, COSV99941253; called by muse, mutect2
- FBLIM1 | c.890+4C>T | Splice Region (SNP) | VAF 69/168 reads (41%) | catalogued as rs1208829229; called by muse, mutect2, varscan2
- FIZ1 | c.899dup p.G301Rfs*83 | Frame Shift Ins (INS) | VAF 38/114 reads (33%) | catalogued as rs1568515490; called by mutect2, pindel, varscan2
- FTSJ3 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 21/431 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs867916796; called by muse, mutect2
- FUT1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 127/336 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.548); catalogued as COSV59568577; called by muse, mutect2, varscan2
- G3BP1 | c.950G>T p.R317I | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62366510; called by muse, mutect2, varscan2
- G6PD | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs387906470, COSV100855021; called by muse, mutect2, varscan2
- GCC2 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 67/194 reads (35%) | catalogued as rs1419608695; called by muse, mutect2, varscan2
- GCFC2 | c.1644dup p.V549Sfs*42 | Frame Shift Ins (INS) | VAF 69/241 reads (29%) | catalogued as rs757231207; called by mutect2, pindel, varscan2
- GJC1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs778423212; called by muse, mutect2, varscan2
- GNAS | c.659del p.P220Lfs*470 | Frame Shift Del (DEL) | VAF 187/606 reads (31%) | catalogued as COSV100007148; called by mutect2, pindel, varscan2
- GPR171 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.393); catalogued as rs753483581; called by muse, varscan2
- GPR35 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs376362528; called by muse, mutect2, varscan2
- GRM2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 102/351 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770473805; called by muse, mutect2, varscan2
- GRP | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.848); catalogued as rs760680754; called by muse, mutect2
- HCFC1 | c.6097G>A p.D2033N | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as rs913223392; called by muse, mutect2, varscan2
- HECTD4 | c.12435C>G p.F4145L | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101108417; called by muse, mutect2, varscan2
- HERC1 | c.5634del p.V1879Lfs*26 | Frame Shift Del (DEL) | VAF 49/114 reads (43%) | catalogued as rs1287865515; called by mutect2, varscan2
- HERC2 | c.2576G>A p.S859N | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1433808896; called by muse, mutect2, varscan2
- HERC5 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs377595074; called by muse, mutect2, varscan2
- HIF1A | c.470del p.K157Rfs*15 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | catalogued as rs1448399181; called by mutect2, pindel, varscan2
- HMGCLL1 | c.62A>G p.H21R | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs369479879; called by muse, mutect2, varscan2
- HNMT | c.554del p.K185Sfs*27 | Frame Shift Del (DEL) | VAF 44/106 reads (42%) | catalogued as COSV54505990; called by mutect2, pindel
- HSPA6 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as COSV59061211, COSV59061348; called by muse, mutect2, varscan2
- IGBP1 | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60557216; called by muse, mutect2
- IGHM | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 25/525 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.691); catalogued as rs782402963; called by muse, mutect2
- IMPG2 | c.1763A>G p.D588G | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs746692897; called by muse, mutect2, varscan2
- INHBA | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777279223, COSV54224492; called by muse, mutect2, varscan2
- INTS6L | c.359dup p.L120Ffs*37 | Frame Shift Ins (INS) | VAF 22/76 reads (29%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- ISOC1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV99434659; called by muse, mutect2, varscan2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 33/101 reads (33%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, pindel, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- KCNC3 | c.1742del p.P581Rfs*27 | Frame Shift Del (DEL) | VAF 62/202 reads (31%) | catalogued as COSV65387095; called by mutect2, pindel, varscan2
- KCNC3 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 212/561 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV65388783; called by muse, mutect2, varscan2
- KCNJ3 | c.802del p.L268Sfs*6 | Frame Shift Del (DEL) | VAF 98/320 reads (31%) | catalogued as COSV54530849; called by mutect2, pindel, varscan2
- KDM3B | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.446); catalogued as rs1255728697, COSV58691083; called by muse, mutect2, varscan2
- KIR3DL2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 178/429 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs376049512, COSV54390025; called by muse, mutect2, varscan2
- KL | c.2674C>T p.Q892* | Nonsense Mutation (SNP) | VAF 45/144 reads (31%) | catalogued as rs1443360460; called by muse, mutect2, varscan2
- KLHL14 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as rs750871626, COSV63832002; called by muse, mutect2, varscan2
- KMT2B | c.6170G>A p.R2057H | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs374062006; called by muse, mutect2, varscan2
- L1CAM | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs200605257, COSV62828942; called by muse, mutect2, varscan2
- LCOR | c.992_994del p.E331del | In Frame Del (DEL) | VAF 82/236 reads (35%) | catalogued as rs1433600940; called by pindel, varscan2
- LEO1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs767042967, COSV55175071; called by muse, varscan2
- LGALS9C | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765706999; called by muse, mutect2
- LGR6 | c.2666del p.P889Lfs*11 (on ENST00000367278 / NM_001017403.1; = p.P837Lfs*11 on NM_021636.3) | Frame Shift Del (DEL) | VAF 46/138 reads (33%) | catalogued as COSV55167248; called by mutect2, pindel, varscan2
- LILRA6 | c.781del p.E261Nfs*26 | Frame Shift Del (DEL) | VAF 59/428 reads (14%) | catalogued as COSV54436642; called by mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 60/154 reads (39%) | catalogued as rs765287063; called by mutect2, varscan2
- LRP2 | c.9088C>T p.Q3030* | Nonsense Mutation (SNP) | VAF 142/414 reads (34%) | catalogued as COSV99789788; called by muse, mutect2, varscan2
- LTB | c.503del p.G168Afs*18 | Frame Shift Del (DEL) | VAF 78/200 reads (39%) | catalogued as rs774553384; called by mutect2, varscan2
- MAP3K21 | c.2105T>C p.I702T | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1399269576; called by muse, mutect2
- MARK2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751037676, COSV100159272; called by muse, mutect2, varscan2
- MDFI | c.-11-4G>A | Splice Region (SNP) | VAF 91/237 reads (38%) | catalogued as rs1374025103; called by muse, mutect2, varscan2
- MLH3 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 59/181 reads (33%) | catalogued as rs770668994, COSV53134876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOSMO | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 91/325 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs755818056; called by muse, mutect2, varscan2
- MRM3 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753173641; called by muse, mutect2, varscan2
- MST1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1157230035; called by muse, mutect2, varscan2
- MYH13 | c.3864T>C p.N1288= | Splice Region (SNP) | VAF 67/189 reads (35%) | catalogued as rs753708003; called by muse, mutect2, varscan2
- MYH3 | c.5425G>A p.G1809R | Missense Mutation (SNP) | VAF 161/510 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750520481, COSV56870963; called by muse, mutect2, varscan2
- MYH3 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56861722; called by muse, mutect2
- MYO9A | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs374336779; called by muse, mutect2, varscan2
- NANS | c.447del p.G150Vfs*5 | Frame Shift Del (DEL) | VAF 68/176 reads (39%) | catalogued as rs749960926; called by mutect2, pindel, varscan2
- NEXMIF | c.4243A>G p.M1415V | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs797045648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFKBIA | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 180/598 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205585858, COSV53755153; called by muse, mutect2, varscan2
- NGEF | c.1841G>A p.C614Y | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs777312558; called by muse, mutect2, varscan2
- NLRP12 | c.887T>C p.F296S | Missense Mutation (SNP) | VAF 182/418 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201151611; called by muse, mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 42/148 reads (28%) | catalogued as rs774343392; called by mutect2, varscan2
- NT5C3A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 39/505 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV54238805; called by muse, mutect2
- ODAM | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68572538; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 121/359 reads (34%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR51G1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 103/266 reads (39%) | catalogued as rs758470497, COSV100429197; called by muse, mutect2, varscan2
- OR52I2 | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 144/411 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763803996, COSV100442860; called by muse, mutect2, varscan2
- OR52L1 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 193/476 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780042578; called by muse, mutect2, varscan2
- PAK5 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 99/273 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs745765163, COSV100781002, COSV62027225; called by muse, mutect2, varscan2
- PALD1 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs143037794; called by muse, mutect2
- PCDH11X | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 23/686 reads (3%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV53463587; called by muse, mutect2
- PCDHA2 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100973875; called by muse, mutect2, varscan2
- PCDHA3 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.158); catalogued as rs139627437, COSV100974134; called by muse, mutect2, varscan2
- PCDHA5 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 252/654 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65352453; called by muse, mutect2, varscan2
- PCDHA7 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV65338739; called by muse, mutect2, varscan2
- PCDHGB4 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs755692863; called by muse, mutect2, varscan2
- PCSK4 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1470123959; called by muse, mutect2, varscan2
- PDE6A | c.2531del p.G844Efs*48 | Frame Shift Del (DEL) | VAF 94/255 reads (37%) | catalogued as rs769569931, COSV54926556; called by mutect2, varscan2
- PGAP6 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs759772953, COSV51740630; called by muse, mutect2, varscan2
- PGR | c.348del p.D116Efs*50 | Frame Shift Del (DEL) | VAF 86/327 reads (26%) | catalogued as COSV54800102; called by pindel, varscan2
- PIEZO1 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs758579805; called by muse, mutect2, varscan2
- PIP4K2A | c.941dup p.D315Rfs*2 | Frame Shift Ins (INS) | VAF 40/111 reads (36%) | catalogued as rs755454854; called by mutect2, varscan2
- PLCB1 | c.10del p.A4Lfs*40 | Frame Shift Del (DEL) | VAF 52/152 reads (34%) | catalogued as COSV100572515; called by mutect2, pindel, varscan2
- PMPCA | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs768196711, COSV65509481; called by muse, mutect2, varscan2
- POLD1 | c.342del p.P116Hfs*53 | Frame Shift Del (DEL) | VAF 78/248 reads (31%) | catalogued as COSV101486889; called by mutect2, pindel, varscan2
- POLR3C | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs893485892, COSV61935945; called by muse, mutect2, varscan2
- POLRMT | c.1495_1497del p.T499del | In Frame Del (DEL) | VAF 52/146 reads (36%) | catalogued as rs1568169482; called by pindel, varscan2
- POPDC3 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 179/485 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs202226180, COSV54644558; called by muse, mutect2, varscan2
- PPARGC1A | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs748836875, COSV53529710; called by muse, mutect2, varscan2
- PPWD1 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54336194; called by muse, mutect2, varscan2
- PRDM7 | c.735del p.L246* | Frame Shift Del (DEL) | VAF 183/578 reads (32%) | catalogued as COSV57986857; called by mutect2, pindel, varscan2
- PRF1 | c.1428dup p.P477Afs*16 | Frame Shift Ins (INS) | VAF 72/297 reads (24%) | catalogued as rs748926167; called by pindel, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs537061158; called by mutect2, varscan2
- PTEN | c.69dup p.D24Rfs*20 | Frame Shift Ins (INS) | VAF 135/418 reads (32%) | catalogued as CI109592; called by mutect2, pindel, varscan2
- PTPRG | c.4003G>A p.V1335I | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1174651225, COSV55638927; called by muse, mutect2, varscan2
- RABEP1 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs757825581, COSV99336328; called by muse, varscan2
- RAI1 | c.3103del p.Q1035Rfs*29 | Frame Shift Del (DEL) | VAF 48/174 reads (28%) | catalogued as rs774789734; called by mutect2, pindel, varscan2
- RDX | c.762dup p.F255Ifs*12 | Frame Shift Ins (INS) | VAF 92/240 reads (38%) | catalogued as rs769184249; called by mutect2, pindel, varscan2
- REV3L | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs200868241, COSV62615834; called by muse, mutect2, varscan2
- RGS12 | c.3870dup p.G1291Rfs*45 | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS12 | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs200575024, COSV58749223; called by muse, mutect2, varscan2
- RGS22 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs773976297, COSV62663446; called by muse, mutect2, varscan2
- RHBDD2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs148559308; called by muse, mutect2, varscan2
- RNF112 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71978965; called by muse, mutect2, varscan2
- RNF152 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100455184; called by muse, mutect2
- ROBO3 | c.2304del p.S769Vfs*235 | Frame Shift Del (DEL) | VAF 56/162 reads (35%) | catalogued as rs1565313066; called by mutect2, pindel, varscan2
- RPL22L1 | c.105G>A p.E35= | Splice Region (SNP) | VAF 65/198 reads (33%) | catalogued as rs755533152; called by muse, mutect2, varscan2
- RPL3 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs11547984; called by muse, mutect2, varscan2
- RPRD2 | c.3209C>G p.S1070C | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV64818922; called by muse, mutect2, varscan2
- RRAGA | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100998087; called by muse, mutect2, varscan2
- RTKN2 | c.394del p.C132Vfs*15 | Frame Shift Del (DEL) | VAF 68/234 reads (29%) | catalogued as rs1237489456; called by mutect2, pindel, varscan2
- RTL1 | c.3400G>A p.A1134T | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1347887909; called by muse, mutect2, varscan2
- SARDH | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs766600569; called by muse, mutect2, varscan2
- SAXO1 | c.748del p.E250Sfs*6 | Frame Shift Del (DEL) | VAF 83/291 reads (29%) | catalogued as COSV65871430; called by mutect2, pindel, varscan2
- SCAMP2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1233118141; called by muse, mutect2, varscan2
- SCN4A | c.2711del p.P904Hfs*17 | Frame Shift Del (DEL) | VAF 30/380 reads (8%) | catalogued as rs1393518799, COSV101438520; called by mutect2, pindel
- SCN5A | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 24/243 reads (10%) | catalogued as rs1553605674; called by muse, mutect2
- SDK2 | c.5593+4C>T | Splice Region (SNP) | VAF 75/224 reads (33%) | catalogued as rs376714866; called by muse, mutect2, varscan2
- SEMA3G | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs775087630; called by muse, mutect2, varscan2
- SFRP1 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 108/294 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs1376969223; called by muse, mutect2, varscan2
- SHISA6 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 46/522 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58653228; called by muse, mutect2
- SIGLEC10 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs536401841, COSV100219200, COSV59484409; called by muse, mutect2, varscan2
- SKOR1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58248000; called by muse, mutect2, varscan2
- SKOR2 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 162/471 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV68551058; called by muse, mutect2, varscan2
- SLC12A4 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771077651; called by muse, mutect2, varscan2
- SLC27A6 | c.1553-2A>G p.X518_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as rs763426461; called by muse, mutect2, varscan2
- SLC2A4 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 150/423 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1270287004; called by muse, mutect2, varscan2
- SLC35F6 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs376660427; called by muse, mutect2, varscan2
- SLC38A3 | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.06); catalogued as rs770243056; called by muse, mutect2, varscan2
- SLC4A2 | c.2074C>A p.R692S | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765272940; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPEG | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1446360847; called by muse, mutect2, varscan2
- SPPL3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs771127814; called by muse, mutect2, varscan2
- STAG1 | c.26T>A p.L9* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | catalogued as COSV52613725; called by muse, mutect2
- SUSD6 | c.497T>C p.M166T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs371726568; called by muse, mutect2, varscan2
- SVIL | c.778del p.R260Gfs*52 (on ENST00000355867 / NM_021738.3; = p.R260Gfs*39 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/181 reads (28%) | catalogued as COSV63446304; called by mutect2, pindel, varscan2
- SYNE1 | c.24975A>G p.S8325= (on ENST00000367255 / NM_182961.4; = p.S8254= on NM_033071.3) | Splice Region (SNP) | VAF 94/258 reads (36%) | catalogued as rs1420188363; called by muse, mutect2, varscan2
- TET3 | c.5243dup p.T1749Hfs*5 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs759623160; called by mutect2, varscan2
- TGM4 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs143965912; called by muse, mutect2
- THSD7A | c.4410T>C p.Y1470= | Splice Region (SNP) | VAF 31/85 reads (36%) | catalogued as rs751772260; called by muse, mutect2
- THSD7A | c.2593C>T p.R865* | Nonsense Mutation (SNP) | VAF 66/139 reads (47%) | catalogued as rs1191902327, COSV70269752; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TJP3 | c.1196del p.G399Afs*31 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as COSV53663110; called by mutect2, pindel, varscan2
- TLE1 | c.1852G>C p.G618R | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64719361, COSV64719460, COSV64723155; called by muse, mutect2, varscan2
- TMC3 | c.2801G>A p.R934H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1028770773, COSV63922102; called by muse, mutect2, varscan2
- TMCC2 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs375049317; called by muse, mutect2, varscan2
- TMEM109 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs199887708; called by muse, mutect2, varscan2
- TMEM132A | c.1081G>A p.V361I (on ENST00000453848 / NM_178031.3; = p.V362I on NM_017870.4) | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs147239477; called by muse, mutect2, varscan2
- TMEM139 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 130/412 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs143413842; called by muse, mutect2, varscan2
- TMEM201 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs752313181, COSV61051216, COSV61052237; called by muse, mutect2, varscan2
- TMEM268 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 71/244 reads (29%) | catalogued as rs781589029, COSV55986611; called by muse, mutect2, varscan2
- TMEM63C | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1211362867, COSV53603010; called by muse, mutect2, varscan2
- TNK2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763672113, COSV57371580; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 43/86 reads (50%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TRIM48 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 132/358 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs754486791, COSV70161112; called by muse, mutect2, varscan2
- TRIOBP | c.6464C>T p.T2155M (on ENST00000644935 / NM_001039141.3; = p.T442M on NM_007032.5) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344381571; called by muse, mutect2, varscan2
- TRPM4 | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 139/391 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762615860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPV5 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1261620650, COSV99520233; called by muse, mutect2, varscan2
- TTC39C | c.535C>A p.L179I (on ENST00000317571 / NM_001135993.2; = p.L118I on NM_153211.4) | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs200601152; called by muse, mutect2, varscan2
- TTK | c.484del p.S162Vfs*9 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | catalogued as rs751135082; called by pindel, varscan2
- TXNRD1 | c.1307C>T p.T436M (on ENST00000525566 / NM_001093771.3; = p.T338M on NM_003330.4) | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144671274, COSV61602909; called by muse, mutect2, varscan2
- UBE2Q1 | c.101del p.G34Afs*8 | Frame Shift Del (DEL) | VAF 50/134 reads (37%) | catalogued as rs759160193; called by mutect2, varscan2
- UBR4 | c.11744G>A p.R3915H | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs760989998; called by muse, mutect2, varscan2
- UBTFL1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 196/588 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs754073678; called by muse, mutect2, varscan2
- USP11 | c.677G>A p.R226H (on ENST00000218348; = p.R183H on NM_001371072.1) | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs778278623; called by muse, mutect2, varscan2
- USP30 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs372711001; called by muse, varscan2
- USP42 | c.3707del p.K1236Rfs*92 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | catalogued as rs759165525, COSV60363391; called by mutect2, varscan2
- UST | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 99/318 reads (31%) | catalogued as rs760552029, COSV66551382; called by mutect2, pindel, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 39/110 reads (35%) | catalogued as rs761528888; called by mutect2, varscan2
- VASP | c.551dup p.P185Tfs*70 | Frame Shift Ins (INS) | VAF 30/96 reads (31%) | catalogued as rs762759767; called by mutect2, varscan2
- VCL | c.2347G>C p.V783L | Missense Mutation (SNP) | VAF 157/414 reads (38%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); catalogued as rs1236482485; called by muse, mutect2, varscan2
- VIRMA | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs996609713, COSV52586043; called by muse, mutect2, varscan2
- VIT | c.1453G>T p.A485S (on ENST00000389975 / NM_001177969.1; = p.A500S on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as rs1050448848; called by muse, mutect2, varscan2
- WNK4 | c.252del p.D85Ifs*32 | Frame Shift Del (DEL) | VAF 55/187 reads (29%) | catalogued as rs747561881; called by mutect2, pindel, varscan2
- WNK4 | c.1338C>G p.D446E | Missense Mutation (SNP) | VAF 32/724 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV55909748; called by muse, mutect2
- XIRP2 | c.3487A>T p.K1163* (on ENST00000628543; = p.K1338* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 88/242 reads (36%) | catalogued as rs989849640; called by muse, mutect2, varscan2
- XPO5 | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 18/162 reads (11%) | catalogued as rs1216168897, COSV54832243; called by muse, mutect2, varscan2
- YJU2 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV53606649; called by muse, mutect2, varscan2
- ZBTB48 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs747997817; called by muse, mutect2, varscan2
- ZMYM6 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100593104; called by muse, mutect2, varscan2
- ZNF430 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237031051; called by muse, mutect2, varscan2
- ZNF777 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.781); catalogued as rs1332477384, COSV56099771; called by muse, mutect2, varscan2
- ZNF783 | c.409del p.E137Rfs*7 | Frame Shift Del (DEL) | VAF 50/163 reads (31%) | catalogued as COSV65184974; called by mutect2, pindel, varscan2
- ZNF865 | c.1136_1138del p.S379del | In Frame Del (DEL) | VAF 47/150 reads (31%) | catalogued as rs1452885543; called by mutect2, pindel, varscan2
- ZSCAN31 | c.126del p.F42Lfs*16 | Frame Shift Del (DEL) | VAF 92/289 reads (32%) | catalogued as rs772469214; called by mutect2, pindel, varscan2
- ZSWIM8 | c.5085del p.Y1696Tfs*17 (on ENST00000605216 / NM_001242487.2; = p.Y1701Tfs*17 on NM_015037.3) | Frame Shift Del (DEL) | VAF 68/188 reads (36%) | catalogued as rs769663113; called by mutect2, varscan2
- ABCA9 | c.4496T>C p.L1499P | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ACAT1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | called by mutect2, varscan2
- ADAMTS7 | c.4902C>A p.P1634= | Splice Region (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- ADCY7 | c.559T>G p.F187V | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ADGRB3 | c.3119G>A p.G1040D | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGAP5 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 157/786 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AGTPBP1 | c.1376C>A p.P459H (on ENST00000357081 / NM_001330701.2; = p.P419H on NM_015239.2) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALMS1 | c.3875A>G p.K1292R | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ALPK3 | c.4364G>A p.S1455N | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ANKH | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKS1B | c.2032del p.S678Afs*27 | Frame Shift Del (DEL) | VAF 90/242 reads (37%) | called by mutect2, varscan2
- AQP11 | c.701A>G p.Q234R | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- AQR | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ARHGAP17 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ARHGAP31 | c.1463A>G p.E488G | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ARID1A | c.6737_6743del p.E2246Afs*19 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel, varscan2
- ASH1L | c.1362A>T p.E454D | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATPAF1 | c.58G>A p.A20T (on ENST00000574428; = p.A43T on NM_022745.4) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ATXN2L | c.2998C>G p.P1000A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- AVP | c.232_234del p.E78del | In Frame Del (DEL) | VAF 64/165 reads (39%) | called by pindel, varscan2
- BIRC3 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- BRD1 | c.742del p.V248Cfs*68 | Frame Shift Del (DEL) | VAF 31/106 reads (29%) | called by mutect2, pindel, varscan2
- BTBD7 | c.969del p.K323Nfs*5 | Frame Shift Del (DEL) | VAF 63/196 reads (32%) | called by mutect2, pindel, varscan2
- C19orf54 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- C22orf42 | c.493+3A>G | Splice Region (SNP) | VAF 86/244 reads (35%) | called by muse, mutect2, varscan2
- C2CD3 | c.4442T>C p.L1481P | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C6orf118 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C9orf72 | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CACNA1H | c.4462G>A p.D1488N | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAMSAP3 | c.1606del p.E536Rfs*27 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- CAPZB | c.71dup p.N24Kfs*14 | Frame Shift Ins (INS) | VAF 65/176 reads (37%) | called by mutect2, pindel, varscan2
- CATSPER2 | c.1391-3C>T | Splice Region (SNP) | VAF 102/325 reads (31%) | called by muse, mutect2, varscan2
- CCDC114 | c.618C>A p.S206R | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CCDC146 | c.832A>T p.N278Y | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CCDC166 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 85/287 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNG1 | c.697-2A>G p.X233_splice | Splice Site (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- CCNI | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, varscan2
- CCNL2 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- CEP162 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHEK2 | c.1461dup p.Y488Ifs*6 (on ENST00000382580 / NM_001005735.2; = p.Y445Ifs*6 on NM_007194.4) | Frame Shift Ins (INS) | VAF 83/284 reads (29%) | called by mutect2, pindel, varscan2
- CIBAR2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 75/203 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CILP2 | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLMN | c.453_454del p.P152Ifs*77 | Frame Shift Del (DEL) | VAF 52/159 reads (33%) | called by pindel, varscan2
- CLMP | c.944A>G p.Q315R | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- COL11A2 | c.1292del p.P431Lfs*79 (on ENST00000341947 / NM_080680.3; = p.P324Lfs*79 on NM_080679.2) | Frame Shift Del (DEL) | VAF 58/160 reads (36%) | called by mutect2, varscan2
- COL1A1 | c.3706A>G p.K1236E | Missense Mutation (SNP) | VAF 27/379 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- COL6A3 | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 117/319 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPPED1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CPZ | c.1514del p.G505Afs*6 (on ENST00000360986 / NM_001014447.3; = p.G494Afs*6 on NM_003652.3) | Frame Shift Del (DEL) | VAF 80/264 reads (30%) | called by mutect2, pindel, varscan2
- CTDP1 | c.2630G>A p.R877K | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CYP26C1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP2A13 | c.1244A>G p.H415R | Missense Mutation (SNP) | VAF 137/400 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DCAF12L1 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DCUN1D3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- DEFB124 | c.138C>A p.H46Q | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHX9 | c.3441_3442insT p.L1148Sfs*27 | Frame Shift Ins (INS) | VAF 80/212 reads (38%) | called by mutect2, pindel*, varscan2
- DLG3 | c.1675G>A p.G559S (on ENST00000374360 / NM_021120.4; = p.G222S on NM_020730.3) | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DNPH1 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNTTIP2 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP7 | c.1142A>T p.Y381F | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- DSPP | c.1650T>G p.S550R | Missense Mutation (SNP) | VAF 234/611 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ELL2 | c.1002del p.A335Pfs*6 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- EMILIN1 | c.1804dup p.C602Lfs*48 | Frame Shift Ins (INS) | VAF 88/272 reads (32%) | called by mutect2, pindel, varscan2
- ENO4 | c.1460G>A p.S487N (on ENST00000622726; = p.S484N on NM_001242699.2) | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENOX1 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- EP300 | c.5765del p.P1922Hfs*38 | Frame Shift Del (DEL) | VAF 110/344 reads (32%) | called by mutect2, pindel, varscan2
- EPC2 | c.1754C>G p.T585R | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ERCC2 | c.1558T>C p.Y520H | Missense Mutation (SNP) | VAF 191/493 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ERI2 | c.1076del p.N359Mfs*37 | Frame Shift Del (DEL) | VAF 83/365 reads (23%) | called by mutect2, pindel, varscan2
- ESRRB | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETV5 | c.770del p.P257Rfs*57 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- EXOC3L4 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FAM111B | c.847del p.I283Lfs*16 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | called by pindel, varscan2
- FAM184B | c.826del p.L276Wfs*8 | Frame Shift Del (DEL) | VAF 49/117 reads (42%) | called by mutect2, pindel, varscan2
- FAM217A | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); called by muse, mutect2
- FGFR1OP2 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FKRP | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLI1 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, varscan2
- FOXN4 | c.505dup p.V169Gfs*133 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | called by mutect2, pindel
- FOXO3 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- FTH1 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 172/528 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GALNT9 | c.454dup p.Q152Pfs*11 | Frame Shift Ins (INS) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GBP3 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2
- GIGYF2 | c.1796del p.P599Lfs*12 | Frame Shift Del (DEL) | VAF 150/479 reads (31%) | called by mutect2, pindel, varscan2
- GNAS | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GPR143 | c.455+2T>C p.X152_splice | Splice Site (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- GRIN1 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 148/371 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GRIPAP1 | c.1006A>T p.N336Y | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, varscan2
- GSAP | c.1856del p.L619* | Frame Shift Del (DEL) | VAF 17/145 reads (12%) | called by mutect2, pindel, varscan2
- GSTM4 | c.568-2A>G p.X190_splice | Splice Site (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- GTF3C5 | c.1470_1475del p.D490_E491del | In Frame Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- GZMH | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- H1-0 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HAGHL | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HARS2 | c.1119dup p.K374Qfs*15 | Frame Shift Ins (INS) | VAF 123/411 reads (30%) | called by mutect2, pindel, varscan2
- HBEGF | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD2 | c.1144dup p.I382Nfs*22 | Frame Shift Ins (INS) | VAF 34/126 reads (27%) | called by mutect2, varscan2
- HECTD4 | c.7361G>A p.G2454D | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.12125G>A p.G4042D | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.639); called by muse, varscan2
- HS6ST1 | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 144/423 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFI44 | c.864dup p.L289Ifs*5 | Frame Shift Ins (INS) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- IGDCC3 | c.1769A>G p.Y590C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- IGHA1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- IGHG3 | c.436-2A>G p.X146_splice | Splice Site (SNP) | VAF 26/100 reads (26%) | called by muse, varscan2
- IGHG3 | c.391-2A>G p.X131_splice | Splice Site (SNP) | VAF 70/512 reads (14%) | called by muse, varscan2
- IL2RA | c.584-3del | Splice Region (DEL) | VAF 34/190 reads (18%) | called by mutect2, pindel, varscan2
- IL2RB | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ILF3 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IQUB | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ISYNA1 | c.1403T>G p.L468R | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); called by muse, varscan2
- ITGB2 | c.1402del p.Q468Sfs*85 (on ENST00000302347; = p.Q444Sfs*85 on NM_000211.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 136/382 reads (36%) | called by mutect2, pindel, varscan2
- IWS1 | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 80/251 reads (32%) | called by mutect2, varscan2
- JARID2 | c.1775del p.P592Lfs*57 | Frame Shift Del (DEL) | VAF 47/126 reads (37%) | called by mutect2, pindel, varscan2
- KBTBD7 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KCNA3 | c.1052A>C p.Q351P | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KCNMB4 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNQ5 | c.2228C>A p.A743E | Missense Mutation (SNP) | VAF 157/413 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KCNS2 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 126/381 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KL | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLF2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KLHL8 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- KMT2D | c.5179C>T p.P1727S | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- KNTC1 | c.3794C>G p.S1265C | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPNB1 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- KRT25 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- LZTS3 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MADD | c.3458A>G p.E1153G | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MAGEB17 | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAMSTR | c.716A>G p.Q239R (on ENST00000318083 / NM_001130915.2; = p.Q136R on NM_182574.2) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP1S | c.2628del p.A878Pfs*132 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- MAST4 | c.953A>G p.Y318C (on ENST00000403625 / NM_001164664.2; = p.Y129C on NM_015183.3) | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAU2 | c.1499G>A p.C500Y | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MCOLN2 | c.1448G>C p.S483T | Missense Mutation (SNP) | VAF 104/325 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MDN1 | c.15623A>G p.K5208R | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MED1 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MED12 | c.3887G>A p.C1296Y | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MED13 | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MED16 | c.1318T>A p.S440T | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); called by muse, varscan2
- MEST | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 106/264 reads (40%) | called by muse, mutect2, varscan2
- MEX3A | c.200del p.G67Afs*60 | Frame Shift Del (DEL) | VAF 33/75 reads (44%) | called by mutect2, varscan2
- MIER2 | c.1585G>C p.A529P | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MINK1 | c.2313C>T p.V771= | Splice Region (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- MOV10L1 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- MPP4 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MPP5 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, varscan2
- MUC5B | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- N4BP1 | c.1804A>G p.I602V | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDST3 | c.1436T>C p.L479P | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEB | c.19709del p.G6570Vfs*69 | Frame Shift Del (DEL) | VAF 42/126 reads (33%) | called by mutect2, pindel, varscan2
- NEK3 | c.181A>G p.N61D | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 64/192 reads (33%) | called by mutect2, pindel, varscan2
- NF1 | c.5986del p.I1996Yfs*16 (on ENST00000358273 / NM_001042492.3; = p.I1975Yfs*16 on NM_000267.3) | Frame Shift Del (DEL) | VAF 61/214 reads (29%) | called by mutect2, pindel, varscan2
- NMT1 | c.1121G>A p.W374* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- NOL11 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NOX5 | c.1819C>T p.H607Y | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPLOC4 | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRG3 | c.148del p.R50Gfs*53 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel
- NUP35 | c.933del p.D312Mfs*26 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | called by mutect2, varscan2
- OPLAH | c.2047G>A p.G683S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1J4 | c.311dup p.I105Hfs*5 | Frame Shift Ins (INS) | VAF 101/274 reads (37%) | called by mutect2, pindel, varscan2
- OR4D5 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PABPC1L | c.931A>G p.R311G | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PALD1 | c.1818G>A p.M606I | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PBX2 | c.222-7_222-5del | Splice Region (DEL) | VAF 40/109 reads (37%) | called by pindel, varscan2
- PCDHA12 | c.558del p.D187Ifs*8 | Frame Shift Del (DEL) | VAF 72/225 reads (32%) | called by mutect2, pindel, varscan2
- PCDHGB4 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCNX2 | c.3604A>G p.N1202D | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PDS5B | c.3717G>T p.Q1239H | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PER1 | c.1171del p.A391Pfs*62 | Frame Shift Del (DEL) | VAF 68/203 reads (33%) | called by mutect2, pindel, varscan2
- PEX10 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 106/295 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PFKL | c.2126T>C p.V709A | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PGR | c.2042dup p.Q682Tfs*14 | Frame Shift Ins (INS) | VAF 103/304 reads (34%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- PHIP | c.3947dup p.Y1316* | Nonsense Mutation (INS) | VAF 39/107 reads (36%) | called by mutect2, pindel, varscan2
- PI4K2A | c.47del p.P16Rfs*198 | Frame Shift Del (DEL) | VAF 39/105 reads (37%) | called by mutect2, pindel, varscan2
- PIK3CA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PIWIL2 | c.211T>G p.L71V | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PJA1 | c.1036G>A p.A346T (on ENST00000361478 / NM_145119.4; = p.A158T on NM_022368.5) | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PLOD1 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLTP | c.1043C>A p.A348D | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PNMA8A | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POM121C | c.1370del p.K457Rfs*40 (on ENST00000607367; = p.K215Rfs*40 on NM_001099415.3) | Frame Shift Del (DEL) | VAF 39/142 reads (27%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.2815del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 57/164 reads (35%) | called by mutect2, pindel, varscan2
- PROM1 | c.809T>C p.L270S | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROX1 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRPF40B | c.142del p.A48Rfs*15 (on ENST00000380281; = p.A42Rfs*15 on NM_012272.3) | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.6694G>A p.A2232T | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PSD2 | c.772del p.D258Mfs*13 | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | called by mutect2, pindel, varscan2
- PSMA7 | c.325C>A p.R109S | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PSMD1 | c.372del p.K124Nfs*11 | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | called by mutect2, varscan2
- PTCHD1 | c.175del p.Q59Sfs*56 | Frame Shift Del (DEL) | VAF 105/348 reads (30%) | called by mutect2, pindel, varscan2
- PTH1R | c.205T>C p.W69R | Missense Mutation (SNP) | VAF 163/470 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRS | c.5783A>C p.E1928A | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWWP3B | c.1851C>A p.C617* | Nonsense Mutation (SNP) | VAF 81/205 reads (40%) | called by muse, mutect2, varscan2
- R3HDM2 | c.2015del p.P672Lfs*34 | Frame Shift Del (DEL) | VAF 44/143 reads (31%) | called by mutect2, pindel, varscan2
- RAB42 | c.242del p.G81Vfs*119 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | called by mutect2, pindel, varscan2
- RABGAP1L | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RAMAC | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RASGRF1 | c.1431del p.R478Afs*7 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- RAVER1 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBFOX1 | c.599del p.K200Rfs*12 | Frame Shift Del (DEL) | VAF 54/184 reads (29%) | called by mutect2, pindel, varscan2
- RGL3 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIC8A | c.1114A>G p.M372V (on ENST00000526104 / NM_001286134.1; = p.M378V on NM_021932.5) | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RIC8B | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2
- RIPK1 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by mutect2, varscan2
- ROBO4 | c.1150-2A>G p.X384_splice | Splice Site (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- RPAP3 | c.226del p.T76Pfs*10 | Frame Shift Del (DEL) | VAF 42/137 reads (31%) | called by mutect2, varscan2
- RPL7A | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SAMD9L | c.3326C>G p.A1109G | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 39/104 reads (38%) | called by mutect2, varscan2
- SCAP | c.2331+2T>C p.X777_splice | Splice Site (SNP) | VAF 80/211 reads (38%) | called by muse, mutect2, varscan2
- SCN4B | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 139/378 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SCN5A | c.4299+1dup p.X1433_splice (on ENST00000333535 / NM_198056.3; = p.X1432_splice on NM_000335.5) | Splice Site (INS) | VAF 34/119 reads (29%) | called by mutect2, pindel, varscan2
- SCN9A | c.3186dup p.G1063Wfs*13 (on ENST00000303354; = p.G1052Wfs*13 on NM_002977.3) | Frame Shift Ins (INS) | VAF 97/345 reads (28%) | called by mutect2, pindel, varscan2
- SF3B1 | c.2199G>T p.K733N | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SHANK3 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SHMT1 | c.1283-1G>T p.X428_splice | Splice Site (SNP) | VAF 18/455 reads (4%) | called by muse, mutect2
- SIMC1 | c.2156G>A p.C719Y (on ENST00000443967 / NM_001308196.1; = p.C304Y on NM_198567.5) | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SLAIN1 | c.866A>G p.Y289C (on ENST00000466548; = p.Y26C on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC15A1 | c.1457del p.N486Mfs*6 | Frame Shift Del (DEL) | VAF 61/175 reads (35%) | called by mutect2, varscan2
- SLC15A3 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SLC16A8 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC35D3 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SLC39A14 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- SLC5A2 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 104/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A19 | c.1298T>C p.F433S | Missense Mutation (SNP) | VAF 147/415 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC9B1 | c.155del p.K52Rfs*9 | Frame Shift Del (DEL) | VAF 40/154 reads (26%) | called by mutect2, pindel, varscan2
- SLIT1 | c.3042dup p.A1015Cfs*22 | Frame Shift Ins (INS) | VAF 103/293 reads (35%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK6 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SMARCA2 | c.4354del p.I1452* | Frame Shift Del (DEL) | VAF 62/195 reads (32%) | called by mutect2, pindel, varscan2
- SMPD3 | c.959A>T p.N320I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- SNTB2 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SOCS5 | c.1061A>T p.Q354L | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPG11 | c.7175A>T p.D2392V | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- SPON2 | c.674_676del p.F225del | In Frame Del (DEL) | VAF 84/224 reads (38%) | called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | PolyPhen benign (0.425); called by muse, mutect2
- STARD13 | c.2912T>C p.L971P (on ENST00000336934 / NM_001243476.3; = p.L853P on NM_052851.3) | Missense Mutation (SNP) | VAF 147/434 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- STEAP3 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STK36 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SUN2 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUOX | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SUPT20HL1 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SVIL | c.2252C>A p.P751H | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SYNE1 | c.22364del p.L7455Cfs*18 (on ENST00000367255 / NM_182961.4; = p.L7384Cfs*18 on NM_033071.3) | Frame Shift Del (DEL) | VAF 26/298 reads (9%) | called by mutect2, pindel
- SYVN1 | c.1427T>C p.V476A (on ENST00000377190 / NM_172230.3; = p.V475A on NM_032431.3) | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TAF4 | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TASOR | c.813dup p.T272Hfs*5 | Frame Shift Ins (INS) | VAF 71/243 reads (29%) | called by mutect2, pindel, varscan2
- TBX3 | c.2210G>T p.R737M (on ENST00000257566 / NM_016569.4; = p.R717M on NM_005996.4) | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- TCAIM | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TCEAL2 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- TCERG1 | c.52del p.E18Sfs*10 | Frame Shift Del (DEL) | VAF 87/252 reads (35%) | called by mutect2, pindel, varscan2
- TCF7 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- TET2 | c.5582del p.G1861Efs*26 | Frame Shift Del (DEL) | VAF 85/242 reads (35%) | called by mutect2, pindel, varscan2
- TEX38 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- TG | c.6995C>T p.T2332I | Missense Mutation (SNP) | VAF 135/343 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THOC6 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TMEM115 | c.468T>G p.C156W | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TMEM161B | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM79 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 129/338 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TMEM86A | c.325T>C p.S109P | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- TMTC1 | c.2441T>A p.V814E (on ENST00000539277 / NM_001193451.2; = p.V706E on NM_175861.3) | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRAPPC10 | c.407del p.N136Tfs*15 | Frame Shift Del (DEL) | VAF 62/200 reads (31%) | called by mutect2, varscan2
- TRIM62 | c.762G>A p.R254= | Splice Region (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- TRPM2 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- TSC22D1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSG101 | c.993_994del p.Y332Cfs*7 | Frame Shift Del (DEL) | VAF 102/320 reads (32%) | called by mutect2, pindel, varscan2
- TTBK1 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- UNK | c.1457del p.P486Lfs*12 | Frame Shift Del (DEL) | VAF 44/141 reads (31%) | called by mutect2, pindel, varscan2
- UNKL | c.1128del p.S377Afs*2 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- USP24 | c.6303del p.G2102Afs*19 | Frame Shift Del (DEL) | VAF 69/242 reads (29%) | called by mutect2, pindel, varscan2
- VPS13B | c.9092A>G p.Y3031C | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- VPS13C | c.10504del p.R3502Efs*5 (on ENST00000644861 / NM_020821.3; = p.R3459Efs*5 on NM_017684.5) | Frame Shift Del (DEL) | VAF 73/264 reads (28%) | called by mutect2, pindel, varscan2
- VSTM5 | c.393dup p.G132Wfs*9 | Frame Shift Ins (INS) | VAF 64/193 reads (33%) | called by mutect2, pindel, varscan2
- WDR61 | c.828+6G>A | Splice Region (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- WIZ | c.2341G>A p.V781M | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- WNT7B | c.196del p.A66Rfs*34 | Frame Shift Del (DEL) | VAF 81/271 reads (30%) | called by mutect2, pindel, varscan2
- YLPM1 | c.2095A>G p.N699D | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZDHHC14 | c.235_237del p.F79del | In Frame Del (DEL) | VAF 76/230 reads (33%) | called by pindel, varscan2
- ZFHX2 | c.6958A>C p.T2320P | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ZFHX2 | c.5480G>A p.G1827D | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ZFHX3 | c.10906_10907del p.S3636Lfs*29 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | called by pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- ZMIZ2 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ZNF148 | c.396dup p.Q133Tfs*27 | Frame Shift Ins (INS) | VAF 82/257 reads (32%) | called by mutect2, pindel, varscan2
- ZNF292 | c.452del p.L151* | Frame Shift Del (DEL) | VAF 54/197 reads (27%) | called by mutect2, pindel, varscan2
- ZNF319 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF646 | c.3362G>A p.S1121N | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF677 | c.1690dup p.S564Kfs*3 | Frame Shift Ins (INS) | VAF 35/94 reads (37%) | called by mutect2, pindel, varscan2
- ZNF829 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- ZNF831 | c.1528G>A p.V510I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ABCB9 | c.1771C>T p.L591= (on ENST00000280560 / NM_019625.4; = p.L548= on NM_019624.3) | Silent (SNP) | VAF 13/140 reads (9%) | catalogued as rs1555271193, COSV54890226; called by muse, mutect2
- ABHD10 | c.528T>C p.A176= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as COSV56326539; called by muse, mutect2
- ACTBL2 | c.1047C>T p.S349= | Silent (SNP) | VAF 60/185 reads (32%) | called by muse, mutect2, varscan2
- AGAP2 | c.87G>A p.P29= | Silent (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- ANO1 | c.252G>A p.Q84= | Silent (SNP) | VAF 55/167 reads (33%) | called by muse, mutect2, varscan2
- APOB | c.11049C>T p.S3683= | Silent (SNP) | VAF 12/269 reads (4%) | called by muse, mutect2
- ARHGAP30 | c.3030T>C p.T1010= (on ENST00000368013 / NM_001025598.2; = p.T799= on NM_181720.3) | Silent (SNP) | VAF 65/202 reads (32%) | called by muse, mutect2, varscan2
- ATR | c.1710T>C p.Y570= | Silent (SNP) | VAF 78/232 reads (34%) | called by muse, mutect2, varscan2
- BBS4 | c.807T>C p.S269= | Silent (SNP) | VAF 197/531 reads (37%) | called by muse, mutect2, varscan2
- BCL11A | c.1896C>T p.S632= (on ENST00000335712 / NM_001365609.1; = p.S666= on NM_018014.4) | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as rs1235206836; called by muse, mutect2, varscan2
- BRAT1 | c.1290C>T p.L430= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs768272447, COSV100500486; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAD | c.6474C>T p.Y2158= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs369443366; called by muse, mutect2, varscan2
- CCDC126 | c.177T>G p.A59= | Silent (SNP) | VAF 14/299 reads (5%) | called by muse, mutect2
- CCKBR | c.921G>A p.T307= | Silent (SNP) | VAF 64/162 reads (40%) | called by muse, mutect2, varscan2
- CDHR3 | c.2358C>T p.T786= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs189227327; called by muse, mutect2, varscan2
- CDK10 | c.645G>A p.T215= (on ENST00000353379 / NM_052988.5; = p.T144= on NM_052987.4) | Silent (SNP) | VAF 123/361 reads (34%) | catalogued as rs775780737, COSV57045944; called by muse, mutect2, varscan2
- CEMIP2 | c.1893G>A p.L631= | Silent (SNP) | VAF 66/377 reads (18%) | called by muse, mutect2, varscan2
- CKAP2L | c.2199G>A p.A733= | Silent (SNP) | VAF 98/238 reads (41%) | catalogued as rs370545195; called by muse, mutect2, varscan2
- CLDN19 | c.208C>T p.L70= | Silent (SNP) | VAF 83/202 reads (41%) | called by muse, mutect2, varscan2
- CLPTM1L | c.51G>T p.V17= | Silent (SNP) | VAF 88/267 reads (33%) | called by muse, mutect2, varscan2
- CPLANE2 | c.81C>T p.C27= | Silent (SNP) | VAF 59/188 reads (31%) | called by muse, mutect2, varscan2
- CST11 | c.183C>T p.D61= | Silent (SNP) | VAF 108/302 reads (36%) | catalogued as COSV63140114, COSV63140225; called by muse, mutect2, varscan2
- CTBP2 | c.387A>C p.A129= | Silent (SNP) | VAF 87/219 reads (40%) | called by muse, mutect2, varscan2
- DEF8 | c.801T>C p.P267= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as rs755452944; called by muse, mutect2, varscan2
- DHX36 | c.3024C>T p.S1008= | Silent (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- DIDO1 | c.1803C>T p.S601= | Silent (SNP) | VAF 58/151 reads (38%) | catalogued as rs370531620; called by muse, mutect2, varscan2
- DKC1 | c.1068T>C p.S356= | Silent (SNP) | VAF 86/220 reads (39%) | called by muse, mutect2, varscan2
- DMXL1 | c.7251A>G p.S2417= | Silent (SNP) | VAF 71/256 reads (28%) | catalogued as rs993445617; called by muse, mutect2, varscan2
- DNAI2 | c.1434G>A p.L478= | Silent (SNP) | VAF 136/383 reads (36%) | called by muse, mutect2, varscan2
- DOP1B | c.1728C>T p.D576= | Silent (SNP) | VAF 72/169 reads (43%) | catalogued as rs761811224, COSV67693795; called by muse, mutect2, varscan2
- DSEL | c.1668T>C p.H556= | Silent (SNP) | VAF 86/266 reads (32%) | catalogued as rs1273326828, COSV59495060; called by muse, mutect2, varscan2
- EFNA5 | c.525C>T p.F175= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs750182897, COSV60948312; called by muse, mutect2, varscan2
- ENTPD1 | c.1272G>A p.L424= | Silent (SNP) | VAF 83/222 reads (37%) | called by muse, mutect2, varscan2
- ERG | c.645T>C p.V215= | Silent (SNP) | VAF 75/239 reads (31%) | called by muse, mutect2, varscan2
- FAM47A | c.2184C>T p.D728= | Silent (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- FAM83H | c.849G>T p.P283= | Silent (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- FBXO40 | c.1368C>T p.H456= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs147462954; called by muse, mutect2, varscan2
- FOXM1 | c.225A>G p.V75= | Silent (SNP) | VAF 99/332 reads (30%) | called by muse, mutect2, varscan2
- FREM3 | c.6240G>A p.Q2080= | Silent (SNP) | VAF 40/263 reads (15%) | called by muse, mutect2, varscan2
- FUT7 | c.441G>A p.S147= | Silent (SNP) | VAF 85/234 reads (36%) | catalogued as rs776134765; called by muse, mutect2, varscan2
- GAD2 | c.72C>T p.G24= | Silent (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- GFRA1 | c.948C>T p.S316= | Silent (SNP) | VAF 153/418 reads (37%) | called by muse, mutect2, varscan2
- GOLIM4 | c.2037G>A p.E679= | Silent (SNP) | VAF 54/198 reads (27%) | catalogued as COSV100463107; called by muse, mutect2, varscan2
- GON4L | c.2160T>C p.T720= | Silent (SNP) | VAF 133/379 reads (35%) | called by muse, mutect2, varscan2
- GPC6 | c.606C>T p.D202= | Silent (SNP) | VAF 78/193 reads (40%) | catalogued as rs376665919, COSV65519523; called by muse, mutect2, varscan2
- GSKIP | c.372C>T p.N124= | Silent (SNP) | VAF 82/214 reads (38%) | catalogued as rs1295946209; called by muse, mutect2, varscan2
- GSS | c.1053C>T p.I351= | Silent (SNP) | VAF 200/518 reads (39%) | catalogued as rs373822828; called by muse, mutect2, varscan2
- HEPHL1 | c.2280C>T p.D760= | Silent (SNP) | VAF 83/202 reads (41%) | catalogued as rs769267363, COSV59892241; called by muse, mutect2, varscan2
- HERC2 | c.111T>C p.N37= | Silent (SNP) | VAF 48/154 reads (31%) | called by muse, mutect2, varscan2
- HSPA1L | c.1728C>T p.C576= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs991571244; called by muse, mutect2, varscan2
- IFFO1 | c.480G>A p.A160= | Silent (SNP) | VAF 83/186 reads (45%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.273G>A p.L91= | Silent (SNP) | VAF 89/240 reads (37%) | catalogued as rs772280279; called by muse, mutect2, varscan2
- IMPDH1 | c.408T>C p.H136= (on ENST00000470772 / NM_001142573.2; = p.H222= on NM_000883.4) | Silent (SNP) | VAF 176/419 reads (42%) | called by muse, mutect2, varscan2
- INTS4 | c.2562G>A p.V854= | Silent (SNP) | VAF 65/200 reads (33%) | called by muse, mutect2, varscan2
- IPO4 | c.1152C>T p.G384= | Silent (SNP) | VAF 74/209 reads (35%) | catalogued as rs752936115, COSV99938253; called by muse, mutect2, varscan2
- IRS1 | c.996C>T p.G332= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100524502; called by muse, mutect2, varscan2
- JARID2 | c.3150C>T p.R1050= | Silent (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- KCNC4 | c.237C>T p.G79= | Silent (SNP) | VAF 108/277 reads (39%) | catalogued as rs749209326, COSV63926013; called by muse, mutect2, varscan2
- KDM2B | c.3255C>T p.C1085= | Silent (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- KIF4A | c.609G>A p.T203= | Silent (SNP) | VAF 82/236 reads (35%) | catalogued as rs901159564; called by muse, mutect2, varscan2
- KIFC2 | c.2124C>T p.G708= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs1407008607; called by muse, mutect2, varscan2
- KRR1 | c.756T>C p.N252= | Silent (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- LAMA3 | c.3876C>T p.I1292= | Silent (SNP) | VAF 132/310 reads (43%) | catalogued as rs372838667; called by muse, mutect2, varscan2
- LAMB4 | c.1896T>C p.A632= | Silent (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- LEMD2 | c.48G>T p.L16= | Silent (SNP) | VAF 92/291 reads (32%) | called by muse, mutect2, varscan2
- LLGL2 | c.1572G>A p.T524= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as rs577005187, COSV51362147; called by muse, mutect2, varscan2
- LRP1 | c.3291T>C p.C1097= | Silent (SNP) | VAF 13/140 reads (9%) | catalogued as COSV54520343; called by muse, mutect2
- LRP2 | c.12930A>G p.V4310= | Silent (SNP) | VAF 157/433 reads (36%) | called by muse, mutect2, varscan2
- MAGEA1 | c.600C>T p.V200= | Silent (SNP) | VAF 88/216 reads (41%) | catalogued as COSV63119258; called by muse, mutect2, varscan2
- MAP3K10 | c.759C>T p.R253= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as rs200143553; called by muse, mutect2, varscan2
- MAST1 | c.1296G>A p.P432= | Silent (SNP) | VAF 144/424 reads (34%) | catalogued as rs866864680, COSV52254761; called by muse, mutect2, varscan2
- MBD5 | c.2397G>T p.S799= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as COSV68697216; called by muse, mutect2, varscan2
- MLLT10 | c.1428T>C p.H476= | Silent (SNP) | VAF 21/219 reads (10%) | catalogued as rs149979889; called by muse, mutect2
- MPHOSPH8 | c.2346G>A p.L782= | Silent (SNP) | VAF 79/189 reads (42%) | catalogued as rs906082822; called by muse, mutect2, varscan2
- MRPS34 | c.354G>C p.L118= | Silent (SNP) | VAF 59/188 reads (31%) | called by muse, mutect2, varscan2
- MS4A14 | c.1128A>G p.T376= | Silent (SNP) | VAF 99/318 reads (31%) | called by muse, mutect2, varscan2
- MUC16 | c.4155C>A p.T1385= | Silent (SNP) | VAF 87/208 reads (42%) | catalogued as COSV67495336; called by muse, mutect2, varscan2
- MYO7A | c.6345C>T p.F2115= | Silent (SNP) | VAF 15/189 reads (8%) | catalogued as rs397516329, COSV60019332; ClinVar: likely benign; called by muse, mutect2
- MYPOP | c.1128C>T p.H376= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs377420159; called by muse, varscan2
- NCOR1 | c.3222C>T p.Y1074= | Silent (SNP) | VAF 86/232 reads (37%) | catalogued as COSV51999113, COSV99250610; called by muse, mutect2, varscan2
- NLGN1 | c.108T>C p.C36= | Silent (SNP) | VAF 114/380 reads (30%) | called by muse, mutect2, varscan2
- NOSIP | c.858C>T p.S286= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as COSV100182401; called by muse, mutect2, varscan2
- NOVA2 | c.690G>A p.P230= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs758277717; called by muse, mutect2, varscan2
- NT5C3A | c.852C>T p.A284= (on ENST00000610140 / NM_001374335.1; = p.A250= on NM_016489.13) | Silent (SNP) | VAF 78/209 reads (37%) | called by muse, mutect2, varscan2
- NXT1 | c.126A>G p.T42= | Silent (SNP) | VAF 26/410 reads (6%) | called by muse, mutect2
- OR4C12 | c.414G>A p.L138= | Silent (SNP) | VAF 118/281 reads (42%) | catalogued as COSV58860538; called by muse, mutect2, varscan2
- OTUD7A | c.2170C>T p.L724= (on ENST00000307050 / NM_001382637.1; = p.L717= on NM_130901.3) | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- PARP1 | c.534G>T p.A178= | Silent (SNP) | VAF 201/534 reads (38%) | catalogued as rs761742692; called by muse, mutect2, varscan2
- PCBP4 | c.996G>A p.S332= (on ENST00000322099 / NM_033010.2; = p.S289= on NM_020418.4) | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs771183208, COSV59056273; called by muse, mutect2, varscan2
- PCDHGA5 | c.1740C>T p.R580= | Silent (SNP) | VAF 143/352 reads (41%) | called by muse, mutect2, varscan2
- PCNX2 | c.3723G>A p.P1241= | Silent (SNP) | VAF 78/219 reads (36%) | catalogued as rs371514176; called by muse, mutect2, varscan2
- PEAK1 | c.1338A>G p.Q446= | Silent (SNP) | VAF 118/335 reads (35%) | called by muse, mutect2, varscan2
- PIGY | c.201C>T p.L67= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- PLXNB3 | c.300C>T p.P100= | Silent (SNP) | VAF 74/195 reads (38%) | called by muse, mutect2, varscan2
- PNMA8A | c.162C>T p.R54= | Silent (SNP) | VAF 71/180 reads (39%) | catalogued as COSV58137618; called by muse, mutect2, varscan2
- PPP1R42 | c.639G>A p.R213= | Silent (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2, varscan2
- PRCP | c.276T>C p.N92= | Silent (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- PREX2 | c.2898G>A p.K966= | Silent (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- PROCR | c.588G>A p.A196= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as rs779402481, COSV53825511, COSV53825851; called by muse, mutect2, varscan2
- PRRT3 | c.942C>T p.D314= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs370676875; called by muse, mutect2, varscan2
- PSME4 | c.2217G>A p.V739= | Silent (SNP) | VAF 23/234 reads (10%) | called by muse, mutect2, varscan2
- QSER1 | c.708C>T p.S236= (on ENST00000399302; = p.S365= on NM_001076786.3) | Silent (SNP) | VAF 19/264 reads (7%) | called by muse, mutect2
- RANBP9 | c.615G>A p.T205= | Silent (SNP) | VAF 48/175 reads (27%) | catalogued as rs1179391643, COSV50581330; called by muse, mutect2, varscan2
- RHOBTB2 | c.420C>T p.C140= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV52573158; called by muse, mutect2, varscan2
- RHOT1 | c.1428C>A p.I476= | Silent (SNP) | VAF 54/132 reads (41%) | called by muse, mutect2, varscan2
- RNF113B | c.231C>T p.H77= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as rs751467561, COSV57435774; called by muse, mutect2, varscan2
- RPTOR | c.3042C>T p.D1014= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs768122802, COSV60804841; called by muse, mutect2, varscan2
- RSPH6A | c.1875C>A p.R625= | Silent (SNP) | VAF 53/144 reads (37%) | called by muse, mutect2, varscan2
- RYR1 | c.13194G>A p.G4398= | Silent (SNP) | VAF 94/214 reads (44%) | catalogued as rs1265421064; called by muse, mutect2, varscan2
- SALL3 | c.3351G>A p.S1117= | Silent (SNP) | VAF 86/221 reads (39%) | catalogued as rs760869162; called by muse, mutect2, varscan2
- SAMD1 | c.738G>A p.E246= | Silent (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- SAMD8 | c.621T>C p.C207= | Silent (SNP) | VAF 90/258 reads (35%) | called by muse, mutect2, varscan2
- SBF1 | c.3984C>T p.D1328= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs375822676; called by muse, mutect2
- SCRIB | c.1218C>A p.T406= | Silent (SNP) | VAF 82/239 reads (34%) | catalogued as rs375603798; called by muse, mutect2, varscan2
- SDK2 | c.1143C>T p.F381= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as rs769338519, COSV101168745; called by muse, mutect2, varscan2
- SENP3 | c.1680T>C p.R560= | Silent (SNP) | VAF 80/231 reads (35%) | called by muse, mutect2, varscan2
- SLC16A2 | c.411C>A p.R137= | Silent (SNP) | VAF 125/333 reads (38%) | catalogued as COSV99330841; called by muse, mutect2, varscan2
- SLC25A43 | c.906G>A p.L302= | Silent (SNP) | VAF 120/332 reads (36%) | called by muse, mutect2, varscan2
- SLC35C2 | c.822T>A p.I274= | Silent (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- SLC39A12 | c.486T>C p.N162= | Silent (SNP) | VAF 53/145 reads (37%) | catalogued as rs372299361; called by muse, mutect2, varscan2
- SLC6A20 | c.1383C>T p.N461= | Silent (SNP) | VAF 84/240 reads (35%) | catalogued as rs772099308, COSV100653842, COSV62071964; called by muse, mutect2, varscan2
- SLC7A4 | c.705C>T p.S235= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as rs776183418; called by muse, mutect2, varscan2
- SLCO1B3 | c.810T>C p.I270= | Silent (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- SLIT3 | c.4167C>T p.Y1389= | Silent (SNP) | VAF 117/286 reads (41%) | catalogued as rs745999328; called by muse, mutect2, varscan2
- SNED1 | c.147C>T p.G49= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs1299282060; called by muse, mutect2, varscan2
- SPOP | c.180A>G p.G60= | Silent (SNP) | VAF 69/169 reads (41%) | catalogued as rs748317501; called by muse, mutect2, varscan2
- SPTBN4 | c.426G>A p.S142= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs147052708, COSV58948764; called by muse, mutect2, varscan2
- SRGAP3 | c.1711C>A p.R571= | Silent (SNP) | VAF 109/272 reads (40%) | catalogued as COSV64540670; called by muse, mutect2, varscan2
- STPG2 | c.1305C>G p.G435= | Silent (SNP) | VAF 59/129 reads (46%) | called by muse, mutect2, varscan2
- SUSD1 | c.1038A>G p.T346= | Silent (SNP) | VAF 85/216 reads (39%) | called by muse, mutect2, varscan2
- TARS2 | c.1389T>C p.C463= | Silent (SNP) | VAF 80/237 reads (34%) | called by muse, mutect2, varscan2
- TBC1D15 | c.2058C>T p.C686= | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- TBKBP1 | c.762C>T p.C254= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1249853285, COSV64653455; called by muse, mutect2, varscan2
- TENM2 | c.201G>A p.R67= | Silent (SNP) | VAF 76/197 reads (39%) | called by muse, mutect2, varscan2
- TIMM17B | c.81T>A p.G27= | Silent (SNP) | VAF 62/209 reads (30%) | called by muse, mutect2, varscan2
- TMED3 | c.471G>A p.Q157= | Silent (SNP) | VAF 71/225 reads (32%) | called by muse, mutect2, varscan2
- TMEM119 | c.474C>A p.P158= | Silent (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- TSGA10 | c.1434C>A p.S478= | Silent (SNP) | VAF 66/175 reads (38%) | called by muse, mutect2, varscan2
- TSNARE1 | c.255T>C p.P85= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- TTC21B | c.1995A>G p.L665= | Silent (SNP) | VAF 116/296 reads (39%) | catalogued as COSV54631974; called by muse, mutect2, varscan2
- TTLL10 | c.1737G>A p.S579= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as rs566976676; called by muse, mutect2, varscan2
- USP11 | c.2247A>G p.P749= (on ENST00000218348; = p.P706= on NM_001371072.1) | Silent (SNP) | VAF 65/181 reads (36%) | catalogued as rs770928956; called by muse, mutect2, varscan2
- USP9X | c.3768A>G p.L1256= | Silent (SNP) | VAF 67/172 reads (39%) | called by muse, mutect2, varscan2
- VPS13A | c.6984T>C p.A2328= | Silent (SNP) | VAF 95/247 reads (38%) | catalogued as rs144477984, COSV62436289; called by muse, mutect2, varscan2
- VPS13B | c.10908A>G p.A3636= | Silent (SNP) | VAF 30/285 reads (11%) | called by muse, varscan2
- YBEY | c.432G>T p.V144= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ZBTB10 | c.1155C>T p.G385= | Silent (SNP) | VAF 84/232 reads (36%) | catalogued as rs1261998688; called by muse, mutect2, varscan2
- ZBTB40 | c.48T>G p.T16= | Silent (SNP) | VAF 116/331 reads (35%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3450C>T p.D1150= | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as rs778153315; called by muse, mutect2, varscan2
- ZNF253 | c.753T>C p.T251= | Silent (SNP) | VAF 105/301 reads (35%) | catalogued as rs13346253; called by muse, mutect2, varscan2
- ZNF319 | c.837G>A p.A279= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as rs914247501; called by muse, mutect2, varscan2
- ZNF536 | c.588C>T p.N196= | Silent (SNP) | VAF 62/146 reads (42%) | called by muse, mutect2, varscan2
- ZNF564 | c.516G>A p.P172= | Silent (SNP) | VAF 27/252 reads (11%) | catalogued as rs375451154; called by muse, mutect2, varscan2
- ZNF808 | c.1143G>A p.A381= | Silent (SNP) | VAF 64/191 reads (34%) | catalogued as rs747195586, COSV100707733; called by muse, mutect2, varscan2
- ADAM9 | c.*1060_*1061del | 3'UTR (DEL) | VAF 78/239 reads (33%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.-52G>A | 5'UTR (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- AFDN | chr6:167976465 G>A | 3'Flank (SNP) | VAF 6/32 reads (19%) | catalogued as rs4708420; called by muse, varscan2
- AGMO | c.1263+59013T>C | Intron (SNP) | VAF 54/165 reads (33%) | called by muse, varscan2
- AGR2 | c.140-113T>C | Intron (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- AL356414.1 | n.274G>T | RNA (SNP) | VAF 106/348 reads (30%) | called by muse, mutect2, varscan2
- ALG2 | c.*370A>G | 3'UTR (SNP) | VAF 111/284 reads (39%) | called by muse, mutect2, varscan2
- ANAPC5 | c.207+1042G>A | Intron (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2, varscan2
- AP3B2 | c.360+52C>T | Intron (SNP) | VAF 46/130 reads (35%) | catalogued as rs761808805; called by muse, mutect2, varscan2
- ARHGAP36 | c.-154G>A | 5'UTR (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52264961, COSV99357050; called by muse, mutect2, varscan2
- ARHGEF17 | c.3270+185del | Intron (DEL) | VAF 29/75 reads (39%) | called by mutect2, pindel, varscan2
- ATP11AUN | n.892G>A | RNA (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
- AUP1 | c.340-93A>G | Intron (SNP) | VAF 58/154 reads (38%) | called by muse, varscan2
130 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 130 other) are not listed here.
